Somatic mutation profile of tumor specimen TCGA-AA-3712-01A (aliquot TCGA-AA-3712-01A-21D-1719-10) from TCGA case TCGA-AA-3712, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 65.2 years (23,831 days).
Specimen TCGA-AA-3712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ac41ded-cd1b-4406-9761-fed1050bd90a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3712-11A (Solid Tissue Normal), aliquot TCGA-AA-3712-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cef3c76e-451b-4068-b603-7340791a205b

The open-access MAF lists 160 somatic variants for this specimen: 104 protein-altering or splice-affecting, 52 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 52, Splice Site 6, Nonsense Mutation 4, RNA 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 138/746 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 60/84 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TSC2 | c.2221-1G>A p.X741_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | catalogued as rs45517218, CS078610, COSV54761663, COSV99052715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 110/248 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV52705750; called by muse, mutect2, varscan2
- ANKRD30A | c.2542-1G>C p.X848_splice (on ENST00000611781; = p.X792_splice on NM_052997.2) | Splice Site (SNP) | VAF 120/990 reads (12%) | catalogued as COSV64608261; called by muse, mutect2, varscan2
- AP3M2 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51528309, COSV51530412; called by muse, mutect2, varscan2
- APC | c.1229T>A p.L410* | Nonsense Mutation (SNP) | VAF 163/260 reads (63%) | catalogued as CD130072, COSV99971223; called by muse, mutect2, varscan2
- ATP5F1A | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV56360144; called by muse, mutect2, varscan2
- ATP8A2 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54946757; called by muse, mutect2, varscan2
- BPIFB1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV53606148; called by muse, mutect2
- CACNA1G | c.6552C>G p.H2184Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61724248; called by muse, mutect2, varscan2
- CACNA1G | c.6553A>C p.S2185R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV61724266; called by muse, mutect2, varscan2
- CACNA2D4 | c.3338C>T p.S1113L | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs200044179; called by muse, mutect2, varscan2
- CCDC197 | c.25A>G p.R9G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100113715; called by muse, mutect2, varscan2
- CD96 | c.1753C>A p.L585I (on ENST00000283285 / NM_198196.3; = p.L569I on NM_005816.5) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51915118; called by muse, mutect2
- CDH9 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV50259331; called by muse, mutect2, varscan2
- CDK7 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV56512983; called by muse, mutect2, varscan2
- CNTNAP2 | c.2930G>C p.G977A | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62166978, COSV62169974; called by muse, mutect2, varscan2
- COL4A1 | c.2626+2T>G p.X876_splice | Splice Site (SNP) | VAF 28/71 reads (39%) | catalogued as COSV65424067; called by muse, mutect2, varscan2
- COL6A6 | c.4436G>A p.G1479E | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62022496; called by muse, mutect2, varscan2
- CPED1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs761946785, COSV60000259; called by muse, mutect2, varscan2
- CYP2A7 | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 97/419 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV52500137; called by muse, mutect2, varscan2
- DIS3L | c.559-1G>C p.X187_splice (on ENST00000319212 / NM_001143688.3; = p.X104_splice on NM_133375.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV59911849; called by muse, mutect2, varscan2
- DMXL1 | c.390C>G p.S130R | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV60709063; called by muse, mutect2, varscan2
- DNTTIP2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 151/411 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV63283911; called by muse, mutect2, varscan2
- DOCK11 | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52237048, COSV99354003; called by muse, mutect2, varscan2
- DSCAM | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV101260802, COSV68024922; called by muse, mutect2, varscan2
- EPN2 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV59060815; called by muse, mutect2, varscan2
- FAM102B | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64239655; called by muse, mutect2, varscan2
- FAM184A | c.2447C>A p.A816D | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58853402; called by muse, mutect2, varscan2
- FAM81B | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as rs746583579, COSV51982028; called by muse, mutect2, varscan2
- FEM1B | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60988294; called by muse, mutect2, varscan2
- FGFR1 | c.1333C>T p.R445W (on ENST00000447712 / NM_023110.3; = p.R443W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781608303, COSV58330773; called by muse, mutect2, varscan2
- FGFR4 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs148292303, COSV52801196, COSV52803650; called by muse, mutect2
- FLII | c.3018G>C p.K1006N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57497481; called by muse, mutect2, varscan2
- GK5 | c.1081dup p.M361Nfs*9 | Frame Shift Ins (INS) | VAF 125/333 reads (38%) | catalogued as rs1178478686; called by mutect2, pindel, varscan2
- GLI3 | c.2255C>T p.S752L | Missense Mutation (SNP) | VAF 128/786 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV67887352; called by muse, mutect2, varscan2
- GPR18 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV61621108; called by muse, mutect2, varscan2
- GUCY1A2 | c.1663C>A p.H555N | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV56483797; called by muse, mutect2, varscan2
- GYS1 | c.824-1G>C p.X275_splice | Splice Site (SNP) | VAF 27/141 reads (19%) | catalogued as COSV54402244; called by muse, mutect2, varscan2
- H4C4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV61590892, COSV61591253, COSV61591576; called by muse, mutect2, varscan2
- HPS4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61103117; called by muse, mutect2, varscan2
- HYDIN | c.6877G>C p.E2293Q | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV59263896; called by muse, mutect2, varscan2
- IL17F | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as COSV60233967; called by muse, mutect2, varscan2
- ITGA10 | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as COSV65196758; called by muse, mutect2, varscan2
- ITGA3 | c.2642G>C p.G881A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV50308642, COSV50336764; called by muse, mutect2, varscan2
- KATNIP | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 112/466 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs370400198; called by muse, mutect2, varscan2
- KIDINS220 | c.4689C>G p.I1563M | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.1); catalogued as rs1262668681, COSV56752275; called by muse, mutect2, varscan2
- LAMA4 | c.1477G>C p.D493H (on ENST00000230538 / NM_001105206.3; = p.D486H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV57895273; called by muse, mutect2, varscan2
- LPA | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as COSV100308375, COSV60310732; called by muse, mutect2, varscan2
- MACF1 | c.15034G>C p.E5012Q (on ENST00000372915; = p.E2945Q on NM_012090.5) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57117102, COSV99247659; called by muse, mutect2, varscan2
- MAST3 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV53219529; called by muse, mutect2, varscan2
- MBD6 | c.1531C>A p.P511T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV63073948; called by muse, mutect2, varscan2
- MCM7 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV57995651, COSV57997264; called by muse, mutect2, varscan2
- MGME1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV100891390; called by muse, mutect2
- MRPS31 | c.985C>G p.H329D | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60266636; called by muse, mutect2, varscan2
- MS4A1 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV61941978; called by muse, mutect2, varscan2
- MUC16 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV67459058; called by muse, mutect2, varscan2
- MYH14 | c.5477G>T p.R1826L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV51814677; called by muse, mutect2
- NMNAT2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200887683, COSV54267717; called by muse, mutect2, varscan2
- NWD1 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100342297, COSV60340766; called by muse, mutect2, varscan2
- OR5W2 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV60614774, COSV60615520; called by muse, mutect2, varscan2
- PCDH11Y | c.1498C>G p.Q500E (on ENST00000400457 / NM_032973.2; = p.Q489E on NM_032971.3) | Missense Mutation (SNP) | VAF 128/336 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV53078739, COSV99292971; called by muse, mutect2, varscan2
- PCDH17 | c.1368G>T p.K456N | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100932220; called by muse, mutect2, varscan2
- PCMTD1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs919070557, COSV62121164; called by muse, mutect2, varscan2
- PCSK9 | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV56161651, COSV56163939; called by muse, mutect2, varscan2
- PFN2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV53523260; called by muse, mutect2, varscan2
- PKD2L2 | c.936C>G p.F312L | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.434); catalogued as COSV51796611; called by muse, mutect2, varscan2
- PKDREJ | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV104387581, COSV53546948; called by muse, mutect2, varscan2
- PKHD1L1 | c.5486G>T p.S1829I | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV65741131; called by muse, mutect2, varscan2
- PPFIBP1 | c.2316C>G p.I772M (on ENST00000318304 / NM_177444.3; = p.I766M on NM_003622.4) | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290022; called by muse, mutect2, varscan2
- PRIM1 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV57717308; called by muse, mutect2, varscan2
- PRRC2A | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63224469; called by muse, mutect2, varscan2
- RBM15 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV63923378; called by muse, varscan2
- RCBTB2 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV60649835; called by muse, mutect2, varscan2
- RNF111 | c.2306A>G p.H769R | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100789086; called by muse, mutect2, varscan2
- RPL13A | c.526-1G>A p.X176_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as rs1306137374, COSV54526286; called by muse, mutect2
- RUFY1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV100106593; called by muse, varscan2
- SALL1 | c.3721C>T p.L1241F | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs773317156, COSV51756029; called by muse, mutect2, varscan2
- SCN3A | c.810G>C p.M270I | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51807131; called by muse, mutect2, varscan2
- SCRIB | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV57585303; called by muse, mutect2, varscan2
- SERPINA9 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV54074164; called by muse, mutect2, varscan2
- SLITRK5 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61522123; called by muse, mutect2, varscan2
- SPTLC1 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52763668; called by muse, mutect2, varscan2
- SYN3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199698408; called by muse, mutect2, varscan2
- TBC1D10A | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV53163584; called by muse, mutect2, varscan2
- TBC1D2B | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56040498; called by muse, mutect2, varscan2
- TBCC | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV55130467; called by muse, mutect2, varscan2
- THOC6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV50187420; called by muse, mutect2, varscan2
- TLN1 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs774077967, COSV59206553; called by muse, mutect2, varscan2
- TMTC2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.34); catalogued as rs763597437, COSV58265228; called by muse, mutect2, varscan2
- UBR5 | c.6768G>A p.M2256I | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99642787; called by muse, mutect2, varscan2
- UGT1A4 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as COSV59386539; called by muse, mutect2, varscan2
- UQCC3 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV53656848; called by muse, varscan2
- VCX | c.356A>C p.E119A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.486); catalogued as COSV100406438; called by muse, varscan2
- VCX2 | c.356A>C p.E119A | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.486); catalogued as COSV57703890, COSV57703918; called by muse, mutect2
- WNT8B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59325068, COSV59325340; called by muse, mutect2, varscan2
- ZBTB43 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 70/92 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as rs1341583507, COSV65094682, COSV65095201; called by muse, mutect2, varscan2
- ZNF250 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.828); catalogued as COSV99481134; called by muse, mutect2, varscan2
- ZNF557 | c.641C>G p.S214C (on ENST00000414706 / NM_001044388.2; = p.S221C on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs1002255434, COSV53273581; called by muse, mutect2, varscan2
- ZNF670 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs765280628, COSV63607942; called by muse, mutect2, varscan2
- ZNF695 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 113/353 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV60585471; called by muse, mutect2, varscan2
- FCGBP | c.1716G>C p.Q572H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2
- PPFIBP1 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADCY3 | c.387G>T p.L129= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as COSV53166466; called by muse, mutect2, varscan2
- ADCY6 | c.3090C>A p.I1030= | Silent (SNP) | VAF 41/208 reads (20%) | catalogued as COSV57167140; called by muse, mutect2, varscan2
- ANK2 | c.10779C>T p.F3593= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV52155999; called by muse, mutect2, varscan2
- ANKLE1 | c.810C>T p.S270= (on ENST00000394458; = p.S216= on NM_152363.6) | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV63920432; called by muse, mutect2, varscan2
- ANKRD24 | c.1224C>T p.D408= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs772227613, COSV53668807; called by muse, mutect2, varscan2
- AP1G1 | c.492C>T p.V164= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs1277975205, COSV55488009; called by muse, mutect2, varscan2
- ATP8B3 | c.2256C>G p.L752= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV59541887, COSV59547169; called by muse, mutect2, varscan2
- BAP1 | c.558G>A p.L186= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1553645792, COSV56233020; ClinVar: likely benign; called by muse, mutect2, varscan2
- BICRAL | c.2052G>A p.E684= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as rs1227691472, COSV100018453, COSV58404734; called by muse, varscan2
- C2orf78 | c.2505C>A p.L835= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV68517202, COSV68518743; called by muse, mutect2, varscan2
- CDC42BPB | c.3027G>A p.P1009= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs376465925; called by muse, mutect2, varscan2
- CNTNAP2 | c.3237C>G p.V1079= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs764132617, COSV62166982; called by muse, mutect2, varscan2
- COL4A5 | c.2601C>T p.I867= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV60359608; called by muse, mutect2, varscan2
- COL9A3 | c.213G>A p.G71= | Silent (SNP) | VAF 241/484 reads (50%) | catalogued as COSV59651977; called by muse, mutect2, varscan2
- FBXO39 | c.594C>G p.L198= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV58621536; called by muse, mutect2, varscan2
- H2AC20 | c.159G>A p.A53= | Silent (SNP) | VAF 103/466 reads (22%) | catalogued as rs111633198, COSV58611798; called by muse, mutect2, varscan2
- HACD3 | c.249G>A p.Q83= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs1234231463, COSV56011263; called by muse, mutect2, varscan2
- IFT52 | c.378T>G p.P126= | Silent (SNP) | VAF 296/646 reads (46%) | catalogued as COSV65974935; called by muse, mutect2, varscan2
- IGLV4-69 | c.120C>A p.L40= | Silent (SNP) | VAF 55/178 reads (31%) | called by muse, mutect2, varscan2
- IGSF3 | c.3366C>T p.N1122= (on ENST00000369486 / NM_001007237.3; = p.N1142= on NM_001542.4) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs772869930, COSV59589274; called by muse, mutect2, varscan2
- ITGB1BP1 | c.463C>T p.L155= | Silent (SNP) | VAF 9/249 reads (4%) | catalogued as rs1284394398; called by muse, mutect2
- KIAA0100 | c.387C>A p.I129= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV66491939; called by muse, varscan2
- KIT | c.303C>T p.H101= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs145333060; ClinVar: likely benign; called by muse, mutect2, varscan2
- LINGO2 | c.543G>A p.Q181= | Silent (SNP) | VAF 62/182 reads (34%) | catalogued as COSV58058927; called by muse, mutect2, varscan2
- LLCFC1 | c.461G>A p.*154= (on ENST00000458732; = p.*123= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/255 reads (18%) | catalogued as COSV62334328; called by muse, mutect2, varscan2
- LMOD2 | c.51C>T p.D17= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as rs367604347; called by muse, mutect2, varscan2
- LRWD1 | c.603C>T p.A201= | Silent (SNP) | VAF 48/287 reads (17%) | catalogued as rs34048535, COSV52960773; called by muse, mutect2, varscan2
- NLGN4Y | c.2301G>A p.S767= | Silent (SNP) | VAF 181/229 reads (79%) | catalogued as rs1259296355, COSV59295347; called by muse, mutect2, varscan2
- OBSCN | c.18405G>A p.P6135= | Silent (SNP) | VAF 53/207 reads (26%) | catalogued as rs548216799, COSV52762718; called by muse, mutect2, varscan2
- ODC1 | c.108T>C p.D36= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV52172084; called by muse, mutect2, varscan2
- OR2G6 | c.168C>T p.H56= | Silent (SNP) | VAF 44/214 reads (21%) | catalogued as rs780841985, COSV100598173, COSV100598367; called by muse, varscan2
- OR2M7 | c.450C>T p.I150= | Silent (SNP) | VAF 236/520 reads (45%) | catalogued as COSV58737754; called by muse, mutect2, varscan2
- PCDHA9 | c.2292G>A p.K764= | Silent (SNP) | VAF 102/517 reads (20%) | catalogued as COSV100969518, COSV65325406; called by muse, varscan2
- PCYT1A | c.39G>A p.K13= | Silent (SNP) | VAF 63/354 reads (18%) | catalogued as COSV53057094; called by muse, mutect2, varscan2
- RAB40A | c.45C>G p.L15= | Silent (SNP) | VAF 56/200 reads (28%) | catalogued as COSV58490988; called by muse, mutect2, varscan2
- RC3H1 | c.2703T>C p.P901= | Silent (SNP) | VAF 30/177 reads (17%) | catalogued as COSV51199369; called by muse, mutect2, varscan2
- RSU1 | c.264C>A p.L88= | Silent (SNP) | VAF 93/545 reads (17%) | catalogued as COSV61710555; called by muse, mutect2, varscan2
- SIRPB1 | c.291G>A p.K97= | Silent (SNP) | VAF 198/1900 reads (10%) | catalogued as COSV53538223; called by muse, mutect2, varscan2
- SLC18A3 | c.204C>T p.G68= | Silent (SNP) | VAF 71/152 reads (47%) | catalogued as COSV60323312; called by muse, varscan2
- SLC35F3 | c.36C>T p.S12= | Silent (SNP) | VAF 73/158 reads (46%) | catalogued as COSV100784899; called by muse, mutect2, varscan2
- SUCO | c.1212G>A p.R404= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs1350151913, COSV55263961; called by muse, mutect2, varscan2
- TAS2R43 | c.228T>C p.N76= | Silent (SNP) | VAF 80/221 reads (36%) | catalogued as rs779687712, COSV67854871; called by muse, mutect2, varscan2
- TBC1D9 | c.345G>C p.V115= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as COSV71307256; called by muse, mutect2, varscan2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as rs1399905400, COSV56405790; called by muse, mutect2, varscan2
- TLN2 | c.3795G>A p.Q1265= | Silent (SNP) | VAF 56/199 reads (28%) | catalogued as COSV60888560; called by muse, mutect2, varscan2
- TOGARAM2 | c.1035C>T p.I345= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as rs377049350; called by muse, mutect2, varscan2
- TYRO3 | c.1776T>C p.A592= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- UQCC3 | c.234G>A p.K78= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV53656860; called by muse, varscan2
- USP9Y | c.6798A>G p.S2266= | Silent (SNP) | VAF 154/197 reads (78%) | catalogued as COSV59099167; called by muse, mutect2, varscan2
- WLS | c.474G>T p.R158= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV52039812; called by muse, mutect2, varscan2
- ZNF366 | c.903G>A p.L301= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV59214967, COSV59215100; called by muse, mutect2, varscan2
- ZNF423 | c.1731C>T p.T577= (on ENST00000563137 / NM_001379286.1; = p.T569= on NM_015069.4) | Silent (SNP) | VAF 83/349 reads (24%) | catalogued as COSV52184538; called by muse, mutect2, varscan2
- ARPP19P1 | n.131G>T | RNA (SNP) | VAF 54/277 reads (19%) | called by muse, mutect2, varscan2
- DCHS2 | n.1442C>A | RNA (SNP) | VAF 53/238 reads (22%) | catalogued as COSV59723378; called by muse, mutect2, varscan2
- RPL13A | c.88+80G>C | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99201380; called by muse, mutect2, varscan2
- RPL13A | c.342+77G>C | Intron (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99201381; called by muse, mutect2, varscan2
